Somatic mutation profile of tumor specimen TCGA-ET-A3BN-01A (aliquot TCGA-ET-A3BN-01A-11D-A19J-08) from TCGA case TCGA-ET-A3BN, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 33.2 years (12,122 days).
Specimen TCGA-ET-A3BN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 086d1e7d-800c-4e28-9bed-7b49a848bf30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A3BN-10A (Blood Derived Normal), aliquot TCGA-ET-A3BN-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/679fbfba-c970-4986-8b73-9b88ba5f59c6

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, In Frame Ins 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.1234G>A p.V412I | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as rs587776478, COSV100523504, COSV58795398; ClinVar: uncertain significance; called by muse, mutect2
- GALNT14 | c.1255A>T p.I419F | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV61108648; called by muse, mutect2, varscan2
- OR56A1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs779071207, COSV57362062, COSV57363619; called by muse, mutect2, varscan2
- PIR | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.511); catalogued as COSV62917841; called by muse, mutect2
- USP49 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.111); catalogued as COSV51897346; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1504_1512dup p.E502_Y504dup | In Frame Ins (INS) | VAF 17/76 reads (22%) | called by mutect2, varscan2
- PITPNM2 | c.2901C>T p.S967= | Silent (SNP) | VAF 11/189 reads (6%) | catalogued as rs759993504, COSV54904877; called by muse, mutect2
- SYTL2 | c.1459+2021T>C | Intron (SNP) | VAF 9/104 reads (9%) | catalogued as COSV60361376; called by muse, mutect2
